OHSU case 2637 — OHSU-CNL: Philadelphia-Negative Neutrophilic Leukemias (CNL/aCML/MDS/MPNu)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Chronic Myeloproliferative Disorders; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/f49b66c1-76af-43b3-9a55-eaed27a2ca51

Diagnoses (1)
1. Atypical chronic myeloid leukemia, BCR/ABL negative: ICD-O-3 morphology code: 9876/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow.

Biospecimens (1 sample)
- Sample 2989R: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
